Somatic mutation profile of tumor specimen TARGET-30-PASRFS-01A (aliquot TARGET-30-PASRFS-01A-01D) from TARGET case TARGET-30-PASRFS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 3.6 years (1,328 days).
Specimen TARGET-30-PASRFS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c29374f-5703-4bf5-9b5c-58edf2687730.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASRFS-10A (Blood Derived Normal), aliquot TARGET-30-PASRFS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa3a42f2-6ef2-421d-b7af-4aafec16823b

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 25, Silent 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARRDC2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs769060128, COSV55845574; called by muse, mutect2, varscan2
- ASAH2 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.057); catalogued as COSV61484126; called by muse, mutect2, varscan2
- BDP1 | c.7404G>T p.M2468I | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV62433283; called by muse, mutect2, varscan2
- CCDC88A | c.5504T>G p.V1835G (on ENST00000436346 / NM_001365480.1; = p.V1807G on NM_018084.5) | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55067221; called by muse, mutect2, varscan2
- CSF1 | c.1358C>A p.A453E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.506); catalogued as COSV60034699; called by muse, mutect2, varscan2
- CSNK2A1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV53936842; called by muse, mutect2, varscan2
- FICD | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs150847777; called by muse, mutect2, varscan2
- LSM2 | c.176A>G p.N59S | Missense Mutation (SNP) | VAF 86/412 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.204); catalogued as COSV65152146; called by muse, mutect2, varscan2
- MBD1 | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV54005069; called by muse, mutect2, varscan2
- NR4A2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59894078; called by muse, mutect2, varscan2
- NUDT19 | c.1020C>A p.H340Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV67959756; called by muse, mutect2, varscan2
- OR5T1 | c.13C>G p.P5A | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV57304099; called by muse, mutect2, varscan2
- OR5T1 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV57304103; called by muse, mutect2, varscan2
- RHAG | c.103C>A p.Q35K | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57705581; called by muse, mutect2, varscan2
- SALL1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs776664263, COSV51761952; called by muse, mutect2, varscan2
- SLCO4A1 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as rs1468863412, COSV53892818, COSV53892953; called by muse, mutect2, varscan2
- SPEF2 | c.4742G>C p.G1581A | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57431248; called by muse, varscan2
- SPTA1 | c.3514G>T p.A1172S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as rs767818064, COSV100935578; called by muse, mutect2, varscan2
- TDRD5 | c.1501G>T p.D501Y | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54247868; called by muse, mutect2, varscan2
- TEX14 | c.1087G>T p.A363S (on ENST00000240361 / NM_001201457.2; = p.A357S on NM_031272.5) | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759758492, COSV53623063; called by muse, mutect2, varscan2
- UMOD | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs749912886, COSV56778201; called by muse, mutect2, varscan2
- WDHD1 | c.1147T>G p.S383A | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV62215076; called by muse, mutect2
- WIPF2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs781272623, COSV60273863; called by muse, mutect2, varscan2
- ZNF770 | c.86G>T p.C29F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62544731; called by muse, mutect2, varscan2
- CLNS1A | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- OR3A1 | c.564C>A p.F188L | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.93); PolyPhen benign (0.048); called by muse, mutect2
- ABO | c.894G>T p.V298= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV71743601, COSV71743627; called by muse, mutect2
- APOB | c.9465A>G p.K3155= | Silent (SNP) | VAF 166/484 reads (34%) | catalogued as COSV51945959; called by muse, mutect2, varscan2
- CLK4 | c.444C>A p.I148= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV60320206; called by muse, mutect2, varscan2
- FOXK2 | c.1671G>T p.V557= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV58881694; called by muse, mutect2, varscan2
- GLI3 | c.3459C>A p.G1153= | Silent (SNP) | VAF 54/131 reads (41%) | catalogued as COSV67892874; called by muse, mutect2, varscan2
- MUC17 | c.6117T>C p.P2039= | Silent (SNP) | VAF 65/218 reads (30%) | catalogued as rs758725701, COSV60298053; called by muse, mutect2, varscan2
- NR0B1 | c.327C>T p.C109= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as CM013587, COSV66763873, COSV66764868; called by muse, mutect2
